Somatic mutation profile of tumor specimen ALCH-ABY1-TTP1-A (aliquot ALCH-ABY1-TTP1-A-1-0-D-A490-36) from ALCHEMIST case ALCH-ABY1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.8 years (20,395 days).
Specimen ALCH-ABY1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b5f197a-75d6-48fd-8c3f-b7b3e5b14441.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABY1-NB1-A (Blood Derived Normal), aliquot ALCH-ABY1-NB1-A-2-0-D-A490-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ee22db0-cd51-4901-89eb-617cb85a468a

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 11, Intron 2, Splice Site 2, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 157/695 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 76/317 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.3312G>T p.K1104N | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV53914188; called by muse, mutect2
- ALDOC | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs1484302705; called by mutect2, varscan2
- AMDHD1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1007205515, COSV57138894; called by muse, mutect2, varscan2
- CASP4 | c.612C>G p.F204L | Missense Mutation (SNP) | VAF 84/656 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV67744946; called by muse, mutect2, varscan2
- COL7A1 | c.6160G>A p.A2054T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs751691247, COSV60400936; called by mutect2, varscan2
- CP | c.267G>C p.W89C | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394623313, COSV99223700; called by muse, mutect2, varscan2
- DGKA | c.841C>A p.R281S | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs758054607; called by muse, mutect2, varscan2
- FAM78B | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV57979229; called by muse, mutect2, varscan2
- GRIN2B | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 69/712 reads (10%) | catalogued as rs1555133111, CM1513515; called by muse, mutect2
- GUCY2F | c.2260G>T p.D754Y | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV54303581; called by mutect2, varscan2
- HECTD2 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 52/454 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761498644; called by muse, mutect2, varscan2
- INPP5J | c.2494G>A p.G832S (on ENST00000331075 / NM_001284285.2; = p.G464S on NM_001002837.2) | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200780809; called by muse, mutect2, varscan2
- NMUR2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs752104368; called by muse, mutect2, varscan2
- OR10T2 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554971; called by muse, mutect2, varscan2
- OR10W1 | c.673C>A p.R225S | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101223793; called by muse, mutect2, varscan2
- SOX8 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs777739719; called by muse, mutect2, varscan2
- ABCF1 | c.248G>T p.R83M | Missense Mutation (SNP) | VAF 102/620 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.873); called by muse, varscan2
- ARID1B | c.2776A>G p.N926D | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ATP2B1 | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); called by muse, mutect2
- ATP8B1 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- CCDC168 | c.11327G>T p.R3776I | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CD151 | c.344_351+2del p.X115_splice | Splice Site (DEL) | VAF 25/218 reads (11%) | called by mutect2, pindel
- CHST7 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2
- COL6A6 | c.1639G>C p.G547R | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- DNAH3 | c.3772A>C p.M1258L | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- IQGAP3 | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 27/329 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- JAK3 | c.3145C>A p.R1049S | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LDLRAP1 | c.747G>T p.W249C | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2
- OR5H6 | c.505C>A p.L169I (on ENST00000642105; = p.L153I on NM_001005479.2) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR8K5 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- PROSER3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- PSMD14 | c.-4-2A>G | Splice Site (SNP) | VAF 39/313 reads (12%) | called by muse, mutect2, varscan2
- RANBP17 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SAMD9L | c.2246C>A p.T749K | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SLC12A6 | c.2320C>T p.P774S (on ENST00000354181 / NM_001365088.1; = p.P723S on NM_005135.2) | Missense Mutation (SNP) | VAF 20/606 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.416); called by muse, mutect2
- TRBV27 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- VCPIP1 | c.375T>G p.Y125* | Nonsense Mutation (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- WDR48 | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); called by muse, mutect2
- ZFP57 | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- ZNF223 | c.671G>T p.R224I | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); called by muse, mutect2
- C19orf81 | c.150C>T p.Y50= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- FAM78B | c.624G>T p.R208= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- GPR143 | c.204C>T p.V68= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- IGSF21 | c.1143T>A p.V381= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- MYH7 | c.67C>A p.R23= | Silent (SNP) | VAF 57/297 reads (19%) | catalogued as COSV100806177, COSV62517999; called by muse, mutect2, varscan2
- THUMPD1 | c.504A>T p.T168= | Silent (SNP) | VAF 68/546 reads (12%) | called by muse, mutect2, varscan2
- TMEM176A | c.267C>T p.A89= | Silent (SNP) | VAF 21/138 reads (15%) | called by muse, mutect2, varscan2
- TSC22D1 | c.930T>C p.T310= | Silent (SNP) | VAF 31/162 reads (19%) | called by muse, mutect2, varscan2
- USP6NL | c.1779T>C p.S593= | Silent (SNP) | VAF 35/241 reads (15%) | called by muse, mutect2, varscan2
- ZAN | c.1860C>T p.T620= | Silent (SNP) | VAF 118/498 reads (24%) | catalogued as COSV61809981; called by muse, mutect2, varscan2
- ZNF548 | c.423G>A p.G141= | Silent (SNP) | VAF 71/462 reads (15%) | called by muse, mutect2, varscan2
- IFI44L | c.479-11A>G | Intron (SNP) | VAF 49/236 reads (21%) | catalogued as rs1557684324; called by muse, mutect2, varscan2
- PRR12 | chr19:49595248 C>T | 5'Flank (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- PRSS16 | c.1150+575C>T | Intron (SNP) | VAF 8/154 reads (5%) | catalogued as rs1185281955; called by muse, mutect2
